Surgical pathology report (de-identified scan), TCGA case TCGA-DX-AB2T, project TCGA-SARC (Sarcoma), tissue source site Memorial Sloan Kettering, specimen TCGA-DX-AB2T-01A (Primary Tumor).

[page 1 of 2]
SURGICAL PATHOLOGY REPORT

....

Clinical Diagnosis & History:

Myofibrosarcoma right thigh. Asymptomatic enlarging mass right thigh.

Specimens Submitted:

1: SP: Radical resection right posterior medial thigh mass

DIAGNOSIS:

- 1) SOFT TISSUE, RIGHT POSTERIOR MEDIAL THIGH; RADICAL RESECTION:
- HIGH GRADE MYXOFIBROSARCOMA (5.1 X 4.9 X 4 CM) DIFFUSELY INVOLVING SKELETAL MUSCLE.
- TUMOR IS PREDOMINANTLY VIABLE.
- ADJACENT AREA OF FAT NECROSIS AND FOREIGN BODY GIANT CELL REACTION CONSISTENT WITH PRIOR SURGICAL SITE.
- MARGINS OF RESECTIONS ARE FREE OF TUMOR.

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

*** Report Electronically Signed Out ***

Gross Description:

1). The specimen is received fresh and labeled "radical resection, right posterior medial thigh mass, long stitch medial adductor, short stitch ischium". The specimen consists of a 22 x 13 x 11 cm portion of soft tissue with an 18.5 x 6 cm ellipse of skin. The deep soft tissues are comprised of muscle, fatty tissue, nerve and tendon. A 9.5 x 0.1 cm linear scar is present on the skin. The margins of resection are inked as follows: deep black, anteromedial red, posteromedial medial green, proximal and distal blue. The specimen is serially sectioned to reveal a 5.1 x 4.9 x 4 cm soft tan, and yellow mucoid mass with no gross evidence of necrosis. The mass appears to invade into adjacent muscle and fat. It is situated 1.5 cm from the posteromedial margin, 3 cm from the anteromedial margin, 2.5 cm and the

** Continued on next page **

ICD.O.3

Fibromyxosarcoma 8811/3
Site: Thigh NOS 049.2
MO 3/10/14

[page 2 of 2]
SURGICAL PATHOLOGY REPORT

----- Page 2 of 2
deep margin, 6.5 cm from the proximal margin, and 6 cm from the distal margin. The specimen is photographed, and two is submitted for TPS. Representative sections are submitted.

Summary of sections:

P - proximal margin
DIS - distal margin
AM - anteromedial margin
PM - posteromedial margin
D - deep margin
S - skin
T - tumor

Summary of Sections:

Part 1: SP: Radical resection right posterior medial thigh mass

Block	Sect.	Site	PCs
1		AM	1
2		D	2
1		DIS	1
1		P	1
2		PM	2
1		S	1
11		T	11

** End of Report **

Prin incomplete resection with
no tx in between. BCR

Source: NCI Genomic Data Commons file 79069cd1-daed-4b2f-8a7d-6d01a28623ed (TCGA-DX-AB2T.E790878E-D0A3-42F5-A5CD-6594DA869B36.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).